Gene-level copy-number profile of tumor specimen BLGSP-71-06-00074-01A from CGCI case BLGSP-71-06-00074, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00074-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e630c5bf-212b-4fca-add6-dd1f839c9795.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00074-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/50fddd51-ad7a-4895-85a9-c82c458309c7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 149; copy number 1: 2,956; copy number 2: 55,808.

Homozygous deletions (total copy number 0; autosomes only): 149 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 40 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr14:105,785,505–106,146,131, 67 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr22:22,689,831–22,905,025, 41 genes: AC244250.2, AC244250.1, IGLV3-24, IGLV2-23, IGLVVI-22-1, IGLV3-22, IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17, IGLV3-16, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 100. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
